Surgical pathology report (de-identified scan), TCGA case TCGA-EE-A2GS, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site University of Sydney, specimen TCGA-EE-A2GS-06A (Metastatic).

[page 1 of 2]
DOB/Age/Sex:
Location:
Requested by:
Requested on:
Specimen Rcvd:
Accession No.:
Copies to:

HISTOPATHOLOGY REPORT

REFERRED MRN

100-0-3
Melanoma amelanotic 8730/3
Site: Subcutaneous, thigh C49.2
lw 6/10/11

CLINICAL DETAILS

Recurrent melanoma (primary left calf). New nodules (subcutaneous) left thigh. Excision of subcutaneous nodules and ilioinguinal dissection. Tissue was sampled for

MACROSCOPIC DESCRIPTION

(Dr.:

Three specimens were received.

1. "LONG STITCH SHORT SAPHENOUS JUNCTION SHORT TIE ON LONG SAPHENOUS VEIN".

Two ellipses of skin which are joined together. One ellipse of skin measures 300mm x 30mm with underlying subcutis to a depth of 30mm and the smaller ellipse measures 70mm x 20mm with underlying fatty tissue to a depth of 20mm. There are two sutures in the specimen container which have fallen off the specimen. At one pole of the specimen is a tail of fatty tissue measuring 100 x 50 x 30mm, presumed to be ilio-inguinal dissection. On the skin surface are several marking circles which are presumed to mark the site of the subcutaneous nodules. The excision margins are all inked blue. Corresponding to the first circle on the skin, in the underlying subcutaneous tissue is a pale tan nodule measuring 7 x 7mm x 5mm. This nodule appears to be located 6mm from the closest deep margin. There is another tan nodule adjacent to it ?lymph node measuring 5mm in maximum dimension. A second nodule is seen in the subcutaneous tissue corresponding to the second circle on the skin. This nodule measures 21mm x 15mm x 20mm and was sampled for his nodule appears to be located 7mm away from the deep margin and 7mm away from the peripheral margin. Corresponding to the third circle on the skin is a further tan nodule in the subcutaneous nodule measuring 9mm x 8mm x 10mm. This nodule is located 7mm from the closest deep margin and 10mm away from the closest lateral margin. Corresponding to the fourth circle on the skin is a further tan nodule 8mm x 5 x 5mm. This nodule is located 11mm from the closest deep margin and 15mm from the closest peripheral margin. Corresponding to the fifth circle on the skin is a subcutaneous nodule measuring 5mm x 5mm x 5mm. This nodule is located 1mm from the deep margin and 10mm away from the closest peripheral margin. The cut surface through the rest of the subcutaneous tissue shows no further lesions.

A&B. The first nodule with the closest surgical margins (A lateral, B medial).

- C. The second nodule with the closest surgical margins.
- D. Nodule number 3 with the closest surgical margin.
- E. Nodule number 4 with the closest surgical margin.
- F. Nodule number 5 with the closest surgical margin.
- G. One lymph node in the ilioinguinal dissection bisected.
- H. One lymph node bisected.
- J. Three lymph nodes.
- K. ?Three lymph nodes.

PLEASE REFER TO THE DIAGRAM.
Macroscopic photographs have been taken.

[page 2 of 2]
Requested by:

✓ MRN/Name:

Location:

Accession:

HISTOPATHOLOGY REPORT

2. "LEFT COMMON AND EXTERNAL ILIAC NODES". Multiple fragments of fatty tissue 50 x 45 x 20mm in aggregate.

A&B. One lymph node bisected.

C-E. One lymph node trisected

F&G. One lymph node bisected.

H. One lymph node in fragments.

J. ?Five lymph nodes.

3. "LEFT OBTURATOR NODES". A fatty piece of tissue 40mm x 15mm x 15mm.

A&B. One large lymph node trisected.

C. One lymph node.

MICROSCOPIC REPORT

1. "LONG STITCH SHORT SAPHENOUS JUNCTION SHORT TIE ON LONG SAPHENOUS VEIN".

The 5 subcutaneous nodules (1A, 1C - 1F) show an undifferentiated non-pigmented epithelioid, naevoid and spindle malignant neoplasm consistent with metastatic amelanotic melanoma. The nodules in 1A and 1F are within definite lymph nodes.

The remaining lymph nodes show (1G-1K) no evidence of malignancy.

Positive: S100 +++, HMB45 +++, Melan A +++

2. "LEFT COMMON AND EXTERNAL ILIAC NODES".

The 8 lymph nodes identified show no evidence of malignancy.

3. "LEFT OBTURATOR NODES".

Two lymph nodes with no evidence of malignancy

SUMMARY

1. Left thigh (subcutis) and lymph nodes (inguinal) - metastatic melanoma (5/12)

/

2. Lymph nodes, left common and external iliac - no evidence of malignancy (0/8)

/

3. Lymph nodes, left obturator - no evidence of malignancy (0/2)

REPORTED BY:

Source: NCI Genomic Data Commons file 2fb4f384-c53c-4d6b-9fa2-de862758c886 (TCGA-EE-A2GS.57868CFE-20D2-4893-BF42-8E94E290D42F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).